Somatic mutation profile of tumor specimen 0DO5FP from CCDI case PBCCAW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,370 days).
Specimen 0DO5FP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b4805a5-42e0-4aa3-8df1-3364620fd548.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO5DY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a41d1219-2b67-44c6-ad38-e24d3d3da816

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMOD3 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 168/512 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs144761436; ClinVar: uncertain significance; called by muse, varscan2
- PRKAG1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 106/583 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1304648370, COSV100305188; called by muse, varscan2
- TLCD1 | c.98T>A p.V33E | Missense Mutation (SNP) | VAF 154/522 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs753772028; called by muse, varscan2
- ADGRV1 | c.501G>T p.M167I | Missense Mutation (SNP) | VAF 232/1006 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, varscan2
- FAM217A | c.255T>A p.F85L | Missense Mutation (SNP) | VAF 94/790 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, varscan2
- NAB1 | c.1400A>G p.Y467C | Missense Mutation (SNP) | VAF 218/1110 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.776); called by muse, varscan2
- SMCR8 | c.1611C>T p.Y537= | Silent (SNP) | VAF 182/659 reads (28%) | catalogued as rs1464676724; called by muse, varscan2
- ANKZF1 | c.-21C>T | 5'UTR (SNP) | VAF 219/492 reads (45%) | called by muse, varscan2
